Somatic mutation profile of tumor specimen TCGA-KP-A3W1-01A (aliquot TCGA-KP-A3W1-01A-11D-A228-09) from TCGA case TCGA-KP-A3W1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,902 days).
Specimen TCGA-KP-A3W1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb3fe06-9f3b-4db2-9e0a-3e6c91273097.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KP-A3W1-10A (Blood Derived Normal), aliquot TCGA-KP-A3W1-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66f4db0c-ab35-4368-aef0-67338670b215

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 32, Silent 11, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM994748, COSV52661145, COSV52810143, COSV53120183; called by muse, mutect2, varscan2
- ACSBG2 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV99397265; called by muse, mutect2, varscan2
- C1RL | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV99864498; called by muse, mutect2
- CACNA1A | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs1434942721, COSV64193791; ClinVar: uncertain significance; called by mutect2, varscan2
- CDC5L | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101014844, COSV65176120; called by muse, mutect2
- COL1A1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1213427451, CM033358, COSV56808434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISPLD2 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs779857159, COSV99295478; called by muse, mutect2, varscan2
- CTTN | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100097305; called by muse, varscan2
- CYP11B1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.717); catalogued as COSV99454788, COSV99455674; called by muse, mutect2, varscan2
- DNAJC30 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99736371; called by muse, mutect2, varscan2
- GADD45A | c.147-2A>T p.X49_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100921459; called by muse, mutect2, varscan2
- IFT140 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763180833, COSV101276299; called by muse, mutect2, varscan2
- ITPR3 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100967069; called by muse, mutect2, varscan2
- LRP1B | c.11384G>A p.G3795E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101253977; called by muse, mutect2, varscan2
- LZTR1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs747430075, COSV53147792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR1 | c.2266A>G p.T756A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100901993; called by muse, mutect2, varscan2
- NT5C1B | c.781C>T p.R261C (on ENST00000359846 / NM_001199086.2; = p.R201C on NM_033253.4) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV58394741; called by muse, mutect2, varscan2
- OR4K15 | c.94C>T p.R32W (on ENST00000305051; = p.R8W on NM_001005486.1) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs775032710, COSV100521053, COSV59301860; called by muse, mutect2, varscan2
- PABPC1L | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs772962499, COSV99407604; called by muse, mutect2, varscan2
- PLEKHH3 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52217128; called by muse, mutect2, varscan2
- PPP2CA | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99196028; called by muse, mutect2, varscan2
- PTOV1 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as rs764573893, COSV99681614; called by muse, mutect2, varscan2
- RYR1 | c.1794C>T p.V598= | Splice Region (SNP) | VAF 8/168 reads (5%) | catalogued as COSV62099816; called by muse, mutect2
- SPOP | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753231, COSV61654230; called by muse, mutect2, varscan2
- SREBF1 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99888398, COSV99888492; called by muse, mutect2, varscan2
- SRPK3 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1175746484, COSV99472996; called by muse, mutect2
- TLE2 | c.1588T>C p.W530R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99504104; called by muse, mutect2, varscan2
- TMC6 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs750556964, COSV100129963; called by muse, mutect2, varscan2
- TNXB | c.12159G>T p.Q4053H (on ENST00000647633; = p.Q3806H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV100926025; called by muse, mutect2, varscan2
- TRIM28 | c.586+1G>A p.X196_splice | Splice Site (SNP) | VAF 8/131 reads (6%) | catalogued as COSV53402160, COSV99448815; called by muse, mutect2
- TTLL9 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs770951589, COSV60595004; called by mutect2, varscan2
- TTN | c.32432C>A p.P10811H (on ENST00000591111; = p.P9884H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen benign (0.223); catalogued as COSV100599836; called by muse, mutect2, varscan2
- ZNF551 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99989822; called by muse, mutect2, varscan2
- ANKRD26 | c.572dup p.Q192Afs*19 | Frame Shift Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.872_882del p.Q291Lfs*2 | Frame Shift Del (DEL) | VAF 16/23 reads (70%) | called by mutect2, pindel, varscan2
- FETUB | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LIF | c.541_570del p.K181_K190del | In Frame Del (DEL) | VAF 24/54 reads (44%) | called by mutect2, pindel
- POLR2A | c.3452C>G p.A1151G | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ALK | c.459T>C p.G153= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101201468; called by muse, mutect2, varscan2
- APOOL | c.306C>T p.V102= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1390553358, COSV100920806; called by muse, mutect2, varscan2
- ATP10B | c.1521G>A p.R507= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV58782176; called by muse, mutect2, varscan2
- CAMK2B | c.474C>T p.F158= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1367462372, COSV51659321; called by muse, mutect2
- LAP3 | c.1305C>T p.F435= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs373038748, COSV99884108; called by mutect2, varscan2
- MYCT1 | c.72C>T p.I24= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100924042; called by muse, mutect2, varscan2
- PCDHGB3 | c.1338C>T p.N446= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV54024177; called by muse, mutect2, varscan2
- PLEKHG4 | c.2316C>T p.R772= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs544577020, COSV100430731; called by muse, mutect2, varscan2
- SLC24A3 | c.1791C>T p.F597= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs148467681; called by muse, mutect2, varscan2
- SLC32A1 | c.918C>T p.F306= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99461924; called by muse, mutect2, varscan2
- SUMO4 | c.240T>C p.D80= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99644601; called by muse, mutect2, varscan2
